Surgical pathology report (de-identified scan), TCGA case TCGA-36-2532, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2532-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Consultation Report

TCGA - 36 - 2532

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

**Ordering
Physician:**

Final Diagnosis:

1. Right and left ovaries and fallopian tubes; bilateral salpingo-oophorectomy:

A. Poorly differentiated serous carcinoma of the ovary:

i. High grade [Grade 3/3].

ii. Tumor size: 25 cm [first ovary: 13cm, second ovary: 12cm].

iii. Tumor totally replaces normal ovary.

iv. Tumor present on outer surface of both ovaries.

v. Lymphovascular invasion is present.

B. Pelvic washings (cytology) positive for tumor.

C. Please see diagnosis comment.

2. Uterus and rectal peritoneum, hysterectomy:

A. High grade serous carcinoma involving the peritoneum.

B. Benign inactive endometrium.

C. Endometrial polyp.

D. Leiomyoma.

E. Unremarkable cervix.

3. Left pelvic lymph nodes, excisional biopsy:

[page 2 of 4]
- A. Two benign lymph nodes.
- B. Negative for malignancy.

4. Omentum, omentectomy: Positive for invasive high grade serous carcinoma.

5. Para-aortic lymph node, excisional biopsy:
- A. One benign lymph node.
- B. Negative for malignancy.

Final Diagnosis Comment:

Sections from the specimen labelled "right and left ovaries and tubes" show high grade serous carcinoma involving both ovaries. Tumor is identified on the surface of the ovaries, in the peritoneal washings, on the peritoneal surface and in the omentum. Selected slides are reviewed with

Clinical History as Provided by Submitting Physician:

Pelvic mass

Ovarian/tubal

- A. R and L ovaries and tubes
- B. Uterus, cervix, parietal peritoneum
- C. Left pelvic node
- D. Omentum
- E. Para aortic node

Specimens Received:

- A: right + left ovaries + tubes
- B: uterus, cervix, rectal peritoneum
- C: left pelvic node
- D: omentum
- E: para aortic node

Gross Description:

Specimen is received into five containers, each labelled with the patient name.

[page 3 of 4]
The first container labelled with "right and left ovaries and tubes", and it is 925 g of bilateral salpingo-oophorectomy specimen with multiple fragments of tumor tissue. Both ovaries are replaced by the tumor, one ovary measuring 13 X 9 X 10 cm, the other one measuring 12 X 10 X 6 cm. Also there is a separately submitted tumor tissue measuring 9 X 5 X 4 cm. The tumor presents on the serosal surface in both ovaries. Fallopian tubes identified, one measuring 4 cm X 0.2, the other one measuring 5 cm X 0.5 cm. The cut surface of the tumor is solid partially cystic the cystic part represent 10% of the tumor. The cut surface of the solid part is gray/yellow no necrosis identified grossly, and the representative sections are submitted as follows:

A1 -the frozen section, submitted in toto as A1
A2-A14 -the tumor
A15-A16 -the fallopian tubes

Container #2 labelled with "uterus, cervix, rectal peritoneum" and consists of a 65 g total hysterectomy with attached peritoneum on the anterior surface of the uterus, the uterus and cervix measuring 7 X 4 X 2.5 cm. There is a subserosal fibroid identified in the fundus. It is measuring 2 cm in diameter. Bivalved specimen shows anterior endometrial polyp measuring 2.5 X 0.5 X 0.8 cm. Otherwise, the endometrium, myometrium, and cervix are grossly unremarkable. The peritoneal surface shows multiple adhesions, otherwise grossly unremarkable. Representative sections are submitted as follows:

B1-B2 -recto-endocervix, anterior and posterior respectively
B3 -anterior endometrial polyp
B4-B5 -anterior and posterior endometrium and myometrium respectively
B6 -cul-de-sac
B7-B8 -fibroid
B9-B12 -peritoneum

Container #3 labelled with "left pelvic node". It is two lymph nodes, one measuring 0.6, the other one measuring 0.5 cm in diameter, and the lymph nodes submitted in toto as C1.

Container #4 labelled with "omentum", and it is omentum fatty tissue measuring 24 X 6 X 1 cm. On serial sectioning throughout the fat, there is a gray-white firm area measuring 1.5 cm in diameter. The remainder of the omental fat is grossly unremarkable, and the representative sections submitted as follows:

D1-D2 -the firm area
D3 -unremarkable omentum

Container #5 labelled with "para aortic node" and consists of a 0.6 lymph node submitted in toto as E1.

[page 4 of 4]
Intraoperative Consultation:

FSA1: GROSS:

Fragmented 923 gm tumor, tumor on serosa, ?tubal or ovarian, tube disappears into tumor.

PROVISIONAL DIAGNOSIS:

Poorly differentiated adeno CA, consistent with serous CA.

Source: NCI Genomic Data Commons file 6eb5cd4d-60ec-4493-b565-a6a15aa5d434 (TCGA-36-2532.D99B756C-2A3C-48CD-844E-CE61F811C3A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).